Gene-level copy-number profile of tumor specimen MP2PRT-PAPPIJ-TMP1-A from MP2PRT case MP2PRT-PAPPIJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,232 days).
Specimen MP2PRT-PAPPIJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ebb4049e-1d8a-425b-9ce9-e1bc524d2085.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPPIJ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/af39315e-5851-42b8-99d4-e4e6531a1c6a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 282; copy number 1: 908; copy number 2: 56,287; copy number 3: 157; copy number 4: 750; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 282 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,245,596, 39 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:150,982,506–151,048,774, 2 genes: AC023469.2, AC023469.1.
- chr6:26,043,227–26,240,793, 29 genes (within-gene range 0–2): H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6.
- chr13:19,818,121–19,818,619, 1 gene: ST6GALNAC4P1.
- chr14:22,168,429–22,552,156, 88 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,538,344, 123 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:46,635,595–46,691,226, 3 genes, copy number 7: PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 908. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
